Gene-level copy-number profile of tumor specimen HCM-CSHL-0617-C22-01B from HCMI case HCM-CSHL-0617-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 86.3 years (31,521 days).
Specimen HCM-CSHL-0617-C22-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 85a9ccfd-fa17-4a73-8a44-3729b539ccc5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0617-C22-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/d85b9b23-3d6f-41fa-9099-70f62ae6351c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 12,533; copy number 2: 38,957; copy number 3: 4,347; copy number 4: 2,986; copy number 5: 29; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–49,528,981, 27 genes (within-gene range 0–1): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11.
- chr14:50,418,501–51,257,655, 25 genes (within-gene range 0–1): MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,330,120–153,361,023, 3 genes, copy number 5: PGLYRP4, RNU6-160P, S100A9.
- chr1:223,538,007–224,010,612, 12 genes, copy number 6: CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3.
- chr8:36,987,977–37,965,953, 26 genes, copy number 5 (within-gene range 4–5): AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1.

Autosomal genes at a single copy (total copy number 1): 9,677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
